Somatic mutation profile of tumor specimen 0DPZTJ from CCDI case PBCCXB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Maxillary sinus; Age at diagnosis: 17.4 years (6,342 days).
Specimen 0DPZTJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c301e11-c39b-43e8-858f-78bc1408045a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPZUB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce23447e-6c1c-4f66-95a2-9fb30e7071b5

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Nonsense Mutation 2, Intron 2, RNA 1, Frame Shift Ins 1, Splice Region 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 63/350 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGAP36 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 124/337 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs759041751, COSV52267857; called by muse, mutect2, varscan2
- ARID1A | c.3331G>T p.E1111* | Nonsense Mutation (SNP) | VAF 93/463 reads (20%) | catalogued as COSV100249984; called by muse, mutect2, varscan2
- CUBN | c.3802C>T p.R1268C | Missense Mutation (SNP) | VAF 56/722 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs747558831, COSV64713018; called by muse, mutect2
- DAP3 | c.916A>G p.I306V | Missense Mutation (SNP) | VAF 169/466 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.203); catalogued as rs1477244495; called by muse, mutect2, varscan2
- DPP9 | c.1327C>T p.R443C (on ENST00000598800; = p.R472C on NM_139159.5) | Missense Mutation (SNP) | VAF 59/817 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs532896006; called by muse, mutect2
- ENG | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 263/615 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs751787590, COSV61226477; called by muse, mutect2, varscan2
- GUCY2D | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 202/469 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99643888; called by muse, mutect2, varscan2
- HUWE1 | c.12865G>A p.D4289N | Missense Mutation (SNP) | VAF 149/387 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs1556909422, COSV53367177, COSV99471114; called by muse, mutect2, varscan2
- LDLRAP1 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 123/538 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.863); catalogued as rs757349366; called by muse, mutect2, varscan2
- RABEP2 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 100/551 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as rs923556055; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3683C>A p.T1228N | Missense Mutation (SNP) | VAF 54/250 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CLCF1 | c.280T>C p.W94R | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GOLGA6B | c.998A>G p.K333R | Missense Mutation (SNP) | VAF 109/116 reads (94%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- KIAA1549 | c.3853G>A p.D1285N | Missense Mutation (SNP) | VAF 18/532 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- KMT2A | c.7645C>A p.Q2549K | Missense Mutation (SNP) | VAF 23/655 reads (4%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.024); called by muse, mutect2
- MUC5AC | c.6149G>A p.C2050Y | Missense Mutation (SNP) | VAF 177/884 reads (20%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- PAPPA | c.3537_3544dup p.D1182Vfs*11 | Frame Shift Ins (INS) | VAF 136/346 reads (39%) | called by mutect2, varscan2
- PCDHGB4 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 114/264 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROGDI | c.433-3C>A | Splice Region (SNP) | VAF 98/440 reads (22%) | called by muse, mutect2, varscan2
- TGM4 | c.1810G>A p.V604I | Missense Mutation (SNP) | VAF 229/517 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ZBTB37 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 28/748 reads (4%) | called by muse, mutect2
- HK2 | c.1335C>T p.S445= | Silent (SNP) | VAF 235/712 reads (33%) | catalogued as rs761200069; called by muse, mutect2, varscan2
- MN1 | c.2589C>T p.N863= | Silent (SNP) | VAF 117/523 reads (22%) | called by muse, mutect2, varscan2
- SUSD6 | c.867G>A p.T289= | Silent (SNP) | VAF 53/307 reads (17%) | catalogued as rs779583841; called by muse, mutect2, varscan2
- TNN | c.1548C>A p.G516= | Silent (SNP) | VAF 40/566 reads (7%) | called by muse, mutect2
- AC112484.1 | n.796G>T | RNA (SNP) | VAF 197/398 reads (49%) | called by muse, mutect2, varscan2
- CNTROB | c.1571+90A>C | Intron (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- HSF5 | c.-9G>T | 5'UTR (SNP) | VAF 10/140 reads (7%) | catalogued as COSV100051321; called by muse, mutect2
- LRRC7 | c.1421-34A>T | Intron (SNP) | VAF 74/189 reads (39%) | catalogued as rs1415560984; called by muse, mutect2, varscan2
- TKTL1 | chrX:154295783 C>A | 5'Flank (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
